Somatic mutation profile of tumor specimen TCGA-N6-A4VE-01A (aliquot TCGA-N6-A4VE-01A-11D-A28R-08) from TCGA case TCGA-N6-A4VE, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Age at diagnosis: 84.3 years (30,794 days).
Specimen TCGA-N6-A4VE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc185052-d5ee-4bdf-8a9a-377336092712.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N6-A4VE-11A (Solid Tissue Normal), aliquot TCGA-N6-A4VE-11A-12D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1053392e-96e1-482e-83e2-f38a7a762c9e

The open-access MAF lists 72 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 14, Splice Region 2, In Frame Del 2, Frame Shift Del 2, Splice Site 2, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5429A>T p.D1810V | Missense Mutation (SNP) | VAF 121/251 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58615845, COSV58624974; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.1427G>T p.C476F | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57776211, COSV57778123; called by muse, mutect2, varscan2
- ADAM17 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs778386605, COSV100176413; called by muse, mutect2, varscan2
- ADAM22 | c.1568G>A p.C523Y | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287993401; called by muse, mutect2, varscan2
- BCOR | c.4927G>A p.E1643K (on ENST00000378444 / NM_001123385.2; = p.E1609K on NM_017745.6) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100653298; called by muse, mutect2
- CEACAM20 | c.984C>G p.N328K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as rs771908793; called by muse, mutect2, varscan2
- FBLN1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs764230125; called by muse, varscan2
- GABRR2 | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1282171123; called by muse, mutect2
- LYST | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759547330, COSV67706018; called by muse, mutect2, varscan2
- MDGA2 | c.2758T>G p.L920V (on ENST00000399232 / NM_001113498.2; = p.L622V on NM_182830.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100638894, COSV62105064; called by mutect2, varscan2
- OR4L1 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV59850510; called by muse, mutect2, varscan2
- PHLDB1 | c.2515C>G p.R839G | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); catalogued as rs781855779; called by muse, mutect2, varscan2
- PRAMEF17 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 147/160 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1262884128, COSV65816630; called by muse, mutect2, varscan2
- PUS7L | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1221609970; called by muse, mutect2, varscan2
- PXDN | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53227228; called by muse, mutect2, varscan2
- SPTBN5 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs368318926; called by muse, mutect2, varscan2
- TAS2R30 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 94/158 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV67853241; called by muse, varscan2
- TAS2R30 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 101/171 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs776574555; called by muse, varscan2
- TNNT1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52570185; called by muse, mutect2, varscan2
- TP53 | c.804del p.N268Kfs*77 | Frame Shift Del (DEL) | VAF 15/22 reads (68%) | catalogued as COSV53086682, COSV53241270; called by mutect2, pindel, varscan2
- TP53 | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52668406, COSV52782728, COSV52840414; called by muse, mutect2, varscan2
- VPS13B | c.6965A>G p.Y2322C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as rs750125340; called by muse, mutect2, varscan2
- YARS1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as rs147005844, COSV65113391; called by muse, mutect2, varscan2
- ZNF326 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs755848042; called by muse, mutect2, varscan2
- A2ML1 | c.1289A>C p.Q430P | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- AC009779.3 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ANKFY1 | c.3497_3502del p.G1166_G1167del (on ENST00000341657 / NM_001330063.2; = p.G1167_G1168del on NM_016376.5) | In Frame Del (DEL) | VAF 26/28 reads (93%) | called by mutect2, pindel, varscan2
- APP | c.1911T>A p.V637= | Splice Region (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
- BRD3 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 61/64 reads (95%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CACNB4 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH4 | c.169+1G>T p.X57_splice | Splice Site (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- CDIN1 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- CDKL5 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CHD4 | c.3821T>G p.V1274G (on ENST00000357008 / NM_001363606.2; = p.V1287G on NM_001273.5) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSRNP1 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- CYP4B1 | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DPF1 | c.124T>G p.F42V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- EDAR | c.1319C>G p.P440R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ELF1 | c.1576C>G p.P526A | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FNDC1 | c.765A>T p.S255= | Splice Region (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- GPATCH1 | c.1893-1G>T p.X631_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- GPR149 | c.1655G>T p.C552F | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPRASP1 | c.3173del p.G1058Vfs*8 | Frame Shift Del (DEL) | VAF 94/252 reads (37%) | called by mutect2, pindel, varscan2
- HIF1AN | c.496A>C p.N166H | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HUWE1 | c.5026C>T p.R1676C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IL18BP | c.319_321del p.I107del | In Frame Del (DEL) | VAF 28/53 reads (53%) | called by mutect2, pindel, varscan2
- MGLL | c.392C>G p.T131R (on ENST00000398104 / NM_001003794.2; = p.T141R on NM_007283.6) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NELFE | c.657T>A p.D219E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR4A1 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PPHLN1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PPP6R3 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- RILPL1 | c.446T>A p.F149Y | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SCN7A | c.2339A>T p.H780L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIP11 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XDH | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H7B | c.1453T>A p.C485S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRM3 | c.912C>T p.G304= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs1167480153; called by muse, mutect2, varscan2
- LSAMP | c.384A>G p.V128= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1280509763; called by muse, mutect2, varscan2
- NFX1 | c.858C>T p.L286= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs1304477108; called by muse, mutect2, varscan2
- OR5V1 | c.672C>A p.T224= | Silent (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- PCLO | c.2232G>A p.Q744= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs780742478, COSV61666957; called by muse, mutect2, varscan2
- PRPH2 | c.501C>A p.G167= | Silent (SNP) | VAF 23/269 reads (9%) | called by muse, mutect2
- PTGER4 | c.904T>C p.L302= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- PTPN13 | c.5592T>A p.V1864= (on ENST00000411767 / NM_080683.3; = p.V1845= on NM_006264.3) | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- SIL1 | c.1248C>G p.P416= | Silent (SNP) | VAF 35/57 reads (61%) | called by muse, mutect2, varscan2
- SYNGR3 | c.228C>G p.L76= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs773729883; called by muse, varscan2
- TMEM130 | c.510C>G p.L170= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV59558733; called by muse, mutect2, varscan2
- WDR19 | c.1905T>C p.H635= | Silent (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- ZNF418 | c.705T>C p.C235= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- ZNF808 | c.1860G>A p.E620= | Silent (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+879G>T | Intron (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2
